Gene-level copy-number profile of tumor specimen TCGA-LN-A49R-01A from TCGA case TCGA-LN-A49R, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 46.8 years (17,109 days).
Specimen TCGA-LN-A49R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.972049ca-8b0c-41d5-b475-0b39b8263897.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A49R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aaccbfd3-2267-4b83-a9aa-05b74c6a43d6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 1,090; copy number 2: 14,819; copy number 3: 16,203; copy number 4: 20,223; copy number 5: 4,584; copy number 6: 2,561; copy number 7: 96; copy number 8: 14; copy number 9: 4; copy number 10: 78; copy number 11: 2; copy number 12: 113; copy number 14: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-LN-A49R-01A-11D-A246-01): tumor purity 0.75, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:55,508,311–56,468,467, 1 gene (within-gene range 0–2): ERC2.
- chr3:55,852,492–56,185,222, 3 genes: MIR3938, RN7SKP45, RNA5SP133.
- chr9:116,687,305–116,877,264, 2 genes: TRIM32, AL157829.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 212 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:189,631,389–189,897,276, 3 genes, copy number 9: TP63, AC078809.1, MIR944.
- chr3:189,969,030–189,969,861, 1 gene, copy number 9: MTAPP2.
- chr4:56,907,876–57,207,459, 10 genes, copy number 10: REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1.
- chr4:65,034,634–65,241,814, 4 genes, copy number 10: AC107058.1, EFL1P2, AC096754.1, LINC02835.
- chr4:73,259,209–73,743,716, 11 genes, copy number 10: AC053527.2, AC053527.1, AC108157.1, ALB, AFP, AFM, LINC02499, AC074250.1, RASSF6, UMLILO, CXCL8.
- chr4:76,214,040–76,783,253, 14 genes, copy number 14 (within-gene range 2–14): FAM47E, AC034139.1, FAM47E-STBD1, STBD1, CCDC158, SNX5P1, RNU6-1000P, AC096743.2, AC096743.1, SHROOM3, AC112249.1, RNU6-145P, MIR4450, MIR548AH.
- chr6:50,411,844–50,521,104, 2 genes, copy number 12: AL132799.1, AL360175.1.
- chr6:64,631,205–64,733,837, 2 genes, copy number 11: HNRNPDP2, AL355357.1.
- chr11:69,012,283–73,931,114, 165 genes, copy number 10–14 (within-gene range 6–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 173. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
